Somatic mutation profile of tumor specimen TCGA-W5-AA2X-01A (aliquot TCGA-W5-AA2X-01A-11D-A417-09) from TCGA case TCGA-W5-AA2X, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IVB; Tumor grade: G4; Age at diagnosis: 67.9 years (24,797 days).
Specimen TCGA-W5-AA2X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b0a3bc2-5b72-45bf-87d5-432378f82577.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2X-10A (Blood Derived Normal), aliquot TCGA-W5-AA2X-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4be772ed-6f3d-4f0d-90bc-869a6154371e

The open-access MAF lists 50 somatic variants for this specimen: 43 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 6, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, Splice Region 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP2 | c.2901C>G p.I967M (on ENST00000547588 / NM_001122772.2; = p.I611M on NM_014770.4) | Missense Mutation (SNP) | VAF 39/419 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99222260; called by muse, mutect2
- ANKS1A | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366374399; called by muse, mutect2, varscan2
- CGGBP1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as COSV100532045; called by muse, mutect2, varscan2
- CGGBP1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.908); catalogued as COSV58851651; called by muse, mutect2, varscan2
- DST | c.12560C>A p.P4187H (on ENST00000361203 / NM_001374722.1; = p.P1775H on NM_015548.5) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.927); catalogued as COSV55010579; called by muse, mutect2
- HELQ | c.3128C>T p.P1043L | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs772341529; called by muse, mutect2, varscan2
- IVL | c.855C>G p.Y285* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV64216391; called by muse, mutect2, varscan2
- MYPN | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV62732298; called by muse, mutect2, varscan2
- OBSCN | c.4399G>A p.A1467T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.963); catalogued as COSV52808561; called by muse, mutect2
- OR52I1 | c.422C>A p.T141K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV56167748; called by muse, mutect2, varscan2
- PHKA1 | c.2215C>T p.R739* | Nonsense Mutation (SNP) | VAF 8/121 reads (7%) | catalogued as rs1197978742; called by muse, mutect2
- PHKA1 | c.163T>C p.W55R | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59810693; called by muse, mutect2, varscan2
- PLOD1 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1286443479; called by muse, mutect2, varscan2
- PTCH1 | c.2323C>A p.L775M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59463490; called by muse, mutect2
- PTPRK | c.3376C>T p.Q1126* (on ENST00000368215 / NM_001291984.2; = p.Q1127* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as rs779054647; called by muse, mutect2, varscan2
- SYNJ1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs201796096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS16 | c.2413T>A p.W805R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.1551G>T p.Q517H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); called by muse, mutect2
- AK3 | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC | c.4240del p.V1414* | Frame Shift Del (DEL) | VAF 19/34 reads (56%) | called by mutect2, pindel, varscan2
- CMBL | c.151_154del p.I51Lfs*11 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- DNAH5 | c.4228A>T p.N1410Y | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DNAH8 | c.4487A>T p.N1496I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELN | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- GTF2IRD1 | c.124-2A>G p.X42_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- HDAC9 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- KEAP1 | c.898_903del p.Y300_L301del | In Frame Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- LRRTM4 | c.1551+4T>C | Splice Region (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- MAP3K21 | c.1168T>A p.S390T | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- MARCO | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MORC1 | c.2783_2799+2del p.X928_splice | Splice Site (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- MYO5B | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NOM1 | c.664G>C p.A222P | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PRPF40A | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PSMD2 | c.1703-13_1707del p.X568_splice | Splice Site (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- RBM4 | c.226A>C p.T76P | Missense Mutation (SNP) | VAF 17/235 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2
- SMC3 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- SND1 | c.2111G>A p.G704D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- STK11 | c.185_186del p.K62Sfs*100 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- TMUB1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.072); called by muse, mutect2
- TRIP11 | c.3844A>T p.K1282* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- VPS33B | c.1418A>G p.D473G | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZSCAN16 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAMTS13 | c.1839T>G p.P613= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV63022537; called by muse, mutect2, varscan2
- CEMIP2 | c.3999A>G p.S1333= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- FILIP1L | c.1653C>G p.T551= (on ENST00000354552 / NM_182909.3; = p.T311= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV58773185; called by muse, mutect2, varscan2
- GPR149 | c.2001G>A p.G667= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV101078152, COSV67668118; called by muse, mutect2, varscan2
- NAV2 | c.492C>A p.I164= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- TANC1 | c.2016G>A p.Q672= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2
- AL132655.6 | chr20:58840288 G>A | 5'Flank (SNP) | VAF 24/50 reads (48%) | catalogued as COSV58333176; called by muse, mutect2, varscan2
